Gene-level copy-number profile of tumor specimen TCGA-VQ-A94O-01A from TCGA case TCGA-VQ-A94O, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 74.8 years (27,306 days).
Specimen TCGA-VQ-A94O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f6b10e14-f431-4235-9a38-9b634b8fffaf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A94O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b89d6d2e-7c14-4577-a4c0-c4a1bab5b025

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 188; copy number 2: 6,970; copy number 3: 20,911; copy number 4: 18,601; copy number 5: 6,487; copy number 6: 2,459; copy number 7: 1,456; copy number 8: 1,241; copy number 9: 15; copy number 10: 237; copy number 11: 9; copy number 12: 863; copy number 13: 359; copy number 40: 19; copy number 48: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A94O-01A-11D-A40Z-01): tumor purity 0.63, ploidy 3.92, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,200 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:224,896,262–225,399,292, 1 gene, copy number 10 (within-gene range 5–10): DNAH14.
- chr2:132,253,154–132,646,582, 12 genes, copy number 7: RNA5-8SP5, MIR663B, CDC27P1, AC097532.1, ZNF806, AC097532.2, AC097532.3, FAM201B, RNU6-175P, GPR39, YBX1P7, RN7SKP103.
- chr3:125,446,650–125,916,384, 22 genes, copy number 8 (within-gene range 4–8): SNX4, Y_RNA, Y_RNA, OSBPL11, AF186996.3, AF186996.2, OR7E130P, OR7E29P, OR7E93P, OR7E53P, OR7E97P, AF186996.1, AC092902.4, AC092902.5, AC092902.2, AC092902.1, MIR548I1, RPS3AP14, AC092902.6, SNRPCP11, LINC02614, ENPP7P4.
- chr3:150,150,538–150,466,431, 7 genes, copy number 7: RPL32P9, AC117386.1, LINC01213, U2, LINC01214, AC018545.1, TSC22D2.
- chr6:167,607–8,064,364, 171 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:46,028,804–122,127,184, 1,093 genes, copy number 7 (broad region; genes not listed).
- chr8:140,940,562–141,308,305, 9 genes, copy number 11 (within-gene range 6–11): RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3.
- chr13:18,467,172–64,076,044, 799 genes, copy number 7–9 (broad region; genes not listed).
- chr13:67,577,624–114,337,626, 575 genes, copy number 7–8 (broad region; genes not listed).
- chr17:1,702,816–2,303,785, 32 genes, copy number 7 (within-gene range 4–7): TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1, RTN4RL1, AC099684.2, AC099684.1, AC099684.3, DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5, MIR132, MIR212, HIC1, SMG6, AC090617.9, AC090617.4, AC090617.6, AC090617.8, AC090617.7, MCUR1P1, RN7SL624P, AC090617.2, AC090617.1.
- chr17:70,778,604–70,779,230, 1 gene, copy number 8: AC007423.1.
- chr19:29,665,459–30,957,192, 22 genes, copy number 13–48: PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr20:87,250–1,620,009, 48 genes, copy number 12 (within-gene range 3–13): DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD, AL049634.2.
- chr20:1,629,152–64,313,132, 1,408 genes, copy number 10–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
